Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A8D1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A8D1-01A (Primary Tumor).

PHYSICIAN INFORMATION

Sex: Male
D.O.B.:
MRN #:
Ref Physn

SPECIMEN INFORMATION

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right and left pelvic lymph nodes, excision:
Six lymph nodes negative for metastatic disease.

- B. Prostate, excision:

Tumor Characteristics:

1. Histologic type: Prostatic adenocarcinoma.
2. Prostate size: 6.5 x 6.0 x 2.5 cm.
3. Tumor quantitation: Tumor occupies roughly 15 to 20% of prostate volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Not identified.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved: Inked apex, base, peripheral.
2. Margins involved: None.

Lymph Node Status:

1. See part A.

Other:

1. Other significant findings: Nodular hyperplasia.
2. pTNM stage: pT2c, N0.

ICD O-3

Adenocarcinoma NOS 8140/3
Site: Prostate NOS (61.9)
4/17/14

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left and right pelvic nodes
B. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is received in formalin labeled with the patient's name left and right pelvic nodes. The specimen consists of a portion of fibroadipose tissue measuring 6.5 x 5.5 x 2.7 cm. Sectioning reveals six possible lymph nodes measuring from 0.5 to 3.0 cm in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node bisected-1; one probable node bisected-2; two probable nodes each bisected-3; one probable node sectioned-4 to 6; one probable node sectioned-7 to 10.

B. The second container B is received labeled with the patient's name prostate. The specimen consists of an intact prostate gland with attached bilateral seminal vesicles and vas deferens. The prostate measures 6.5 x 6.0 x 2.5 cm and weighs 50 grams. The attached seminal vesicles measure in average 2.0 cm in length and 1.5 cm in diameter. The vas deferens measure 1.5 cm in length and 0.2 cm in diameter. Both are grossly unremarkable. The surface of the prostate is gray tan to brown tan with adhesions. The right half has been inked blue and left half has been inked black. The specimen is serially sectioned from apex to base and reveals a gray tan to yellow tan cut surface. A definitive mass is not identified.

Received with the specimen are three cassettes, one green, one yellow, one blue, labeled as follows: right seminal vesicle and vas-1; left seminal vesicle and vas-2; perpendicular sections taken from the margins from apex-3; base-4, prostate submitted from apex to base as follows: level 1 left anterior-5; left posterior-6; right posterior-7; right anterior-8; level 2 left anterior-9; left posterior-10; right posterior-11; right anterior-12; level 3 left anterior-13; left posterior-14; right posterior-15; right anterior-16.

Representative sections are submitted in

Source: NCI Genomic Data Commons file 66ed64ad-c2ff-4991-b1e1-6c3045680fe2 (TCGA-HC-A8D1.6C5B3FD6-3C50-4DF3-9101-D131075F4A5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).